Somatic mutation profile of tumor specimen TCGA-DH-A7UV-01A (aliquot TCGA-DH-A7UV-01A-12D-A34A-08) from TCGA case TCGA-DH-A7UV, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 49.7 years (18,161 days).
Specimen TCGA-DH-A7UV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 624a2493-8282-416a-aea6-d6f0419b0a32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DH-A7UV-10A (Blood Derived Normal), aliquot TCGA-DH-A7UV-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4bfd132-761a-4540-834d-cbf4daf94dda

The open-access MAF lists 31 somatic variants for this specimen: 27 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 22, Silent 4, Frame Shift Del 3, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 30/79 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1036T>C p.Y346H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.24); PolyPhen possibly damaging (0.575); catalogued as COSV100911453, COSV64310562; called by muse, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 22/29 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- ATP6V1G3 | c.76A>G p.K26E | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99811097; called by muse, mutect2, varscan2
- BCOR | c.4751A>G p.N1584S (on ENST00000378444 / NM_001123385.2; = p.N1550S on NM_017745.6) | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.72); PolyPhen benign (0.05); catalogued as COSV100654267; called by muse, mutect2, varscan2
- CBLIF | c.721A>G p.K241E | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1401062936, COSV99951101; called by muse, mutect2, varscan2
- CCNB3 | c.3532A>C p.T1178P | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV99329982; called by muse, mutect2
- CD36 | c.1175T>C p.L392S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99988005; called by muse, mutect2, varscan2
- CNTN4 | c.1996C>A p.P666T | Missense Mutation (SNP) | VAF 101/231 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100639790; called by muse, mutect2, varscan2
- FAM193A | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100219640; called by muse, mutect2
- FREM1 | c.3825A>C p.K1275N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV101085604; called by muse, mutect2, varscan2
- KANK4 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100587746; called by muse, mutect2, varscan2
- KRTAP12-4 | c.212G>C p.C71S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); catalogued as COSV100555692, COSV59971652; called by muse, mutect2, varscan2
- PCDH15 | c.5863C>G p.L1955V | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100228400, COSV57287115; called by muse, mutect2, varscan2
- PSMC1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 10/16 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as COSV99728576; called by muse, mutect2, varscan2
- RNF17 | c.4612C>T p.R1538W | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs773738236, COSV55039293; called by muse, mutect2, varscan2
- SCN9A | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs771227297, COSV57600072; ClinVar: uncertain significance; called by muse, mutect2
- SLC33A1 | c.1541C>G p.S514C | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.319); catalogued as COSV100848344; called by muse, mutect2, varscan2
- ST14 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs142893442; called by muse, mutect2, varscan2
- TMEM266 | c.327A>G p.I109M | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV101189669; called by muse, mutect2, varscan2
- USP3 | c.727T>G p.F243V | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99165812; called by muse, mutect2, varscan2
- VPS18 | c.816C>G p.F272L | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.134); catalogued as COSV99592804; called by muse, mutect2, varscan2
- ZDHHC3 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as rs760297347, COSV99943683; called by muse, mutect2, varscan2
- ATRX | c.1141del p.S381Qfs*33 | Frame Shift Del (DEL) | VAF 105/181 reads (58%) | called by mutect2, pindel, varscan2
- CGN | c.1786_1788del p.K596del | In Frame Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.2546_2547del p.K849Rfs*6 | Frame Shift Del (DEL) | VAF 36/135 reads (27%) | called by mutect2, pindel, varscan2
- SH3D19 | c.1948_1949del p.E650Rfs*9 | Frame Shift Del (DEL) | VAF 16/81 reads (20%) | called by mutect2, pindel, varscan2
- CCT6B | c.1413C>A p.V471= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as COSV100031069, COSV58490259; called by muse, mutect2, varscan2
- FSCN3 | c.558T>C p.D186= | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as rs1403679762, COSV99133977; called by muse, mutect2, varscan2
- SCNN1A | c.102A>G p.E34= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99964989; called by muse, mutect2, varscan2
- TAGAP | c.1722C>T p.H574= | Silent (SNP) | VAF 6/123 reads (5%) | catalogued as rs1360627679, COSV100487681, COSV100487696; called by muse, mutect2
